Somatic mutation profile of tumor specimen MP2PRT-PASTYP-TMP1-A (aliquot MP2PRT-PASTYP-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASTYP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (974 days).
Specimen MP2PRT-PASTYP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ae56967-7c8a-48b5-a444-d9062ae70785.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTYP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTYP-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38f34284-1741-4f4d-a122-c6b12271c6e4

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'Flank 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRN3 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 47/404 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH1 | c.264C>T p.I88= | Silent (SNP) | VAF 76/342 reads (22%) | catalogued as rs1420450352, COSV55441366; called by muse, mutect2, varscan2
- SPRED1 | c.1188C>T p.S396= | Silent (SNP) | VAF 45/436 reads (10%) | catalogued as rs773409045, COSV54437424; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins AAC | 3'Flank (INS) | VAF 29/190 reads (15%) | called by mutect2, pindel, varscan2
